Somatic mutation profile of tumor specimen TCGA-QH-A870-01A (aliquot TCGA-QH-A870-01A-11D-A36O-08) from TCGA case TCGA-QH-A870, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 38.6 years (14,082 days).
Specimen TCGA-QH-A870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a85e2acf-f8ab-42ac-8042-c04a44015690.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A870-10A (Blood Derived Normal), aliquot TCGA-QH-A870-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c106959-977e-40fd-aa53-b6692d91cb5e

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 150/408 reads (37%) | catalogued as COSV100971383, COSV64875775; called by muse, mutect2, varscan2
- CHM | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV100753417, COSV100753621; called by muse, mutect2, varscan2
- HELZ2 | c.3458G>A p.G1153D (on ENST00000467148 / NM_001037335.2; = p.G584D on NM_033405.3) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1158748057, COSV100915699; called by muse, mutect2, varscan2
- NEDD9 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); catalogued as COSV101053427; called by muse, mutect2, varscan2
- OLR1 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 57/153 reads (37%) | catalogued as rs374394285; called by muse, mutect2, varscan2
- RBM25 | c.1467+1G>A p.X489_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99999038; called by muse, mutect2, varscan2
- RCC2 | c.1467C>T p.V489= | Splice Region (SNP) | VAF 28/95 reads (29%) | catalogued as COSV100965199; called by muse, mutect2, varscan2
- SUFU | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.983); catalogued as COSV64015189; called by muse, mutect2, varscan2
- TENM1 | c.6511C>T p.R2171C | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763650152, COSV100949485; called by muse, mutect2, varscan2
- TENM1 | c.2652-2A>T p.X884_splice | Splice Site (SNP) | VAF 5/70 reads (7%) | catalogued as COSV100950877; called by muse, mutect2
- TP53 | c.681del p.D228Tfs*19 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as COSV52809847, COSV53096994, COSV53684875; called by mutect2, pindel*, varscan2
- TRPM8 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61220540; called by muse, mutect2
- ZNF703 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs753504182, COSV100521802, COSV58999161; called by muse, mutect2, varscan2
- ATP10D | c.307_308del p.F103Pfs*34 | Frame Shift Del (DEL) | VAF 44/124 reads (35%) | called by mutect2, pindel, varscan2
- PHF3 | c.1377del p.I459Mfs*23 | Frame Shift Del (DEL) | VAF 40/113 reads (35%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.1212C>T p.G404= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99293764; called by muse, mutect2, varscan2
- B4GALNT2 | c.1053C>T p.T351= | Silent (SNP) | VAF 79/200 reads (40%) | catalogued as rs570206637, COSV100302316, COSV55925934; called by muse, mutect2, varscan2
- PCDHB4 | c.2334C>G p.T778= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as COSV99522494; called by muse, mutect2, varscan2
- TSHZ3 | c.3117T>C p.T1039= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99552666; called by muse, mutect2, varscan2
